Gene-level copy-number profile of tumor specimen TCGA-SB-A6J6-01A from TCGA case TCGA-SB-A6J6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 22.5 years (8,233 days).
Specimen TCGA-SB-A6J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.daf466dd-5854-4475-8672-89d1573d6115.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SB-A6J6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e4483f4-1434-46d9-ad91-c2884c98b7a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,184; copy number 3: 8,208; copy number 4: 15,798; copy number 5: 10,243; copy number 6: 9,443; copy number 7: 9,057; copy number 8: 1,747; copy number 9: 2,395; copy number 10: 745.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SB-A6J6-01A-11D-A434-01): tumor purity 0.28, ploidy 4.97, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,140 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–64,591,133, 1,175 genes, copy number 9 (broad region; genes not listed).
- chr8:43,018,424–85,977,154, 632 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr8:86,016,819–86,017,126, 1 gene, copy number 9: AC023194.1.
- chr12:6,438,498–27,695,564, 555 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr12:32,679,200–34,249,958, 32 genes, copy number 9: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr21:10,328,411–46,665,124, 745 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
